CCDI case PBBTPZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5fedaeaf-dc09-48b1-86c1-dbe3119d8a02

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 21.2 years (7,743 days).

Biospecimens (3 samples)
- Sample 0DHX1Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHX2N: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHX3L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
